CCDI case PBCLJU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/0be26351-9bba-46c5-a1b3-fab06fdd224f

Demographics
Sex at birth: male; Race: black or african american.

Biospecimens (3 samples)
- Sample 0DUIWT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUIX2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUIYP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
